Somatic mutation profile of tumor specimen TCGA-21-1075-01A (aliquot TCGA-21-1075-01A-01W-0782-08) from TCGA case TCGA-21-1075, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 57.7 years (21,093 days).
Specimen TCGA-21-1075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e0a321d-7d8c-4ac9-acbb-848270b4838c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1075-11A (Solid Tissue Normal), aliquot TCGA-21-1075-11A-01W-0782-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4895c30a-222f-43e5-a662-19736a17a56d

The open-access MAF lists 207 somatic variants for this specimen: 160 protein-altering or splice-affecting, 46 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 46, Nonsense Mutation 12, Frame Shift Del 4, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 41/67 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 249/333 reads (75%) | hotspot (GDC flag); catalogued as CD951866, COSV52713084, COSV52728511, COSV53025106, COSV53864205; called by muse, varscan2
- A2M | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as COSV59386976; called by muse, mutect2
- ABCC9 | c.3808G>A p.A1270T | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.901); catalogued as COSV99686359; called by muse, mutect2, varscan2
- AC004593.2 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 57/578 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99765581; called by muse, mutect2, varscan2
- ACE | c.3724C>T p.R1242C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1226490350, COSV52010158; called by muse, mutect2, varscan2
- ACSM2B | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100312945; called by muse, mutect2, varscan2
- ADAMTS12 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 133/257 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761157092, COSV61257360, COSV61262119; called by muse, mutect2, varscan2
- AHRR | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327700; called by muse, mutect2, varscan2
- ALMS1 | c.3844A>T p.T1282S | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT tolerated (0.73); PolyPhen benign (0.153); catalogued as COSV100043103; called by muse, varscan2
- ALPK3 | c.2102A>T p.E701V | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.188); catalogued as COSV99361488; called by muse, mutect2, varscan2
- ARC | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV63078086; called by muse, mutect2, varscan2
- ARFGEF1 | c.3725A>G p.H1242R | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as rs747385663, COSV99143334; called by muse, mutect2, varscan2
- ASB5 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV99641916; called by muse, mutect2, varscan2
- ASPM | c.7901A>T p.H2634L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.777); catalogued as COSV99659535, COSV99660773; called by muse, mutect2, varscan2
- ASTN2 | c.3291G>T p.K1097N (on ENST00000313400 / NM_001365069.1; = p.K1046N on NM_014010.5) | Missense Mutation (SNP) | VAF 324/433 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99941116; called by muse, mutect2, varscan2
- ATP8B4 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99466598; called by muse, mutect2, varscan2
- C1QB | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 393/556 reads (71%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100152797; called by muse, varscan2
- C5AR1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as rs200400919, COSV61892222; called by muse, mutect2, varscan2
- CCN2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 171/434 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915339; called by muse, mutect2, varscan2
- CEACAM18 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV101140523; called by muse, mutect2, varscan2
- CENPJ | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 110/144 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1225292635, COSV101121544; called by muse, mutect2, varscan2
- CNOT1 | c.4547G>A p.G1516D | Missense Mutation (SNP) | VAF 196/523 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); catalogued as COSV55322684; called by muse, mutect2, varscan2
- CNTN5 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs201144555, COSV54301785; called by muse, mutect2, varscan2
- COL3A1 | c.4207G>A p.E1403K | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100483402; called by muse, mutect2, varscan2
- COL6A6 | c.6683G>T p.R2228I | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV100650592; called by muse, mutect2, varscan2
- CORO1C | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV54594600; called by muse, mutect2, varscan2
- CRACD | c.2322G>T p.E774D | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV99949664; called by muse, mutect2
- CSKMT | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100649036, COSV100649191; called by muse, mutect2, varscan2
- CSMD3 | c.4478G>T p.G1493V (on ENST00000297405 / NM_001363185.1; = p.G1389V on NM_052900.3) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV52106995, COSV99840689; called by muse, mutect2, varscan2
- CSMD3 | c.4477G>T p.G1493* (on ENST00000297405 / NM_001363185.1; = p.G1389* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV52098361, COSV99823471; called by muse, mutect2, varscan2
- CTNND2 | c.1480G>T p.G494C | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs34001856, COSV100478998; called by muse, mutect2, varscan2
- CYSLTR2 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99935306; called by muse, mutect2, varscan2
- DAP3 | c.796A>T p.N266Y | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100546601; called by muse, mutect2, varscan2
- DAXX | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99802398; called by muse, mutect2, varscan2
- DCDC1 | c.1924C>A p.Q642K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100663856; called by muse, mutect2, varscan2
- DLAT | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as COSV99734856; called by muse, mutect2, varscan2
- DLGAP4 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs1313667136, COSV100211449; called by muse, mutect2, varscan2
- DNAH5 | c.10772G>T p.G3591V | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54214966, COSV99451847; called by muse, mutect2, varscan2
- DSEL | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs765642118, COSV100025883; called by muse, varscan2
- EHHADH | c.1969C>G p.P657A | Missense Mutation (SNP) | VAF 44/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339213115; called by mutect2, varscan2
- EIF3D | c.1070C>G p.A357G | Missense Mutation (SNP) | VAF 26/706 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as COSV99341644; called by muse, mutect2
- EPYC | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV99664762; called by muse, mutect2, varscan2
- ERBB4 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV61534503; called by muse, varscan2
- ERICH3 | c.2691G>T p.Q897H | Missense Mutation (SNP) | VAF 474/645 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV100445038, COSV58607243; called by muse, mutect2, varscan2
- EXTL3 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55036850, COSV99593898; called by muse, varscan2
- FAM47C | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV100792815; called by muse, mutect2, varscan2
- FAT3 | c.12853G>A p.V4285M | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99968063; called by muse, mutect2, varscan2
- FAT4 | c.2248G>T p.A750S | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.96); PolyPhen benign (0.011); catalogued as COSV101271942, COSV101272530; called by muse, mutect2, varscan2
- FCGR3B | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99670658; called by muse, mutect2, varscan2
- FLVCR1 | c.1091A>C p.E364A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100875092; called by muse, mutect2, varscan2
- GEN1 | c.18G>C p.L6F | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438095; called by muse, mutect2
- GGA2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100564788; called by muse, mutect2, varscan2
- GIMAP8 | c.1414C>A p.P472T | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV100217604; called by muse, mutect2, varscan2
- H3-5 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 128/258 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs1018998701, COSV61186971; called by muse, varscan2
- H4C5 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs756223901, COSV100748030; called by muse, mutect2, varscan2
- HCN4 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758468167, COSV56084416, COSV99984381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPC | c.829G>A p.D277N (on ENST00000420743; = p.D264N on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV100193248; called by muse, mutect2, varscan2
- IL4R | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 138/382 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs752744351, COSV99405198; called by muse, mutect2, varscan2
- IMPA2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99302655; called by muse, mutect2, varscan2
- INO80D | c.2437C>T p.R813* | Nonsense Mutation (SNP) | VAF 115/558 reads (21%) | catalogued as rs1412590759, COSV101305865; called by muse, mutect2, varscan2
- KLHL41 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs747444097, COSV99500493; called by muse, mutect2, varscan2
- KRT24 | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV99232100; called by muse, mutect2, varscan2
- KRTAP5-6 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV101191767; called by muse, mutect2, varscan2
- LCT | c.2989del p.V997Lfs*7 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as COSV99070190; called by mutect2, pindel, varscan2
- LHX5 | c.172A>T p.R58W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99922515; called by muse, mutect2, varscan2
- LRRIQ3 | c.1335G>T p.M445I | Missense Mutation (SNP) | VAF 252/328 reads (77%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV100599029; called by muse, varscan2
- LTA4H | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99957189; called by muse, mutect2, varscan2
- LY6G6C | c.58A>T p.I20F | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV101009750; called by muse, mutect2, varscan2
- LY75 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as rs752898621, COSV55103445, COSV55106814; called by muse, mutect2, varscan2
- MACROH2A2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952355; called by muse, mutect2
- MALT1 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100618805; called by muse, mutect2, varscan2
- MAST4 | c.524A>T p.Y175F | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.956); catalogued as COSV101282578; called by muse, mutect2, varscan2
- MBOAT1 | c.1261G>T p.V421L | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100209038, COSV61127130; called by muse, mutect2, varscan2
- MICAL2 | c.4840C>T p.P1614S | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV99812035; called by muse, mutect2, varscan2
- MOS | c.912C>G p.F304L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100322934, COSV100323016; called by muse, mutect2
- MRPL20 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV61224693; called by muse, mutect2, varscan2
- MYH13 | c.1350C>A p.D450E | Missense Mutation (SNP) | VAF 100/448 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.274); catalogued as rs1288493981, COSV99354717; called by muse, varscan2
- NALCN | c.973T>C p.F325L | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99216464; called by muse, mutect2, varscan2
- NCAPG | c.1108T>C p.Y370H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99266084; called by muse, mutect2, varscan2
- NFAM1 | c.509C>G p.T170S | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100215986; called by muse, mutect2, varscan2
- NLRC3 | c.2724G>C p.Q908H | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV100073070; called by muse, mutect2, varscan2
- NOS3 | c.3205del p.V1069Cfs*24 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as COSV99872247; called by mutect2, pindel, varscan2
- NRG2 | c.1712C>A p.A571D | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV56833686, COSV99180606; called by muse, mutect2, varscan2
- OBSCN | c.17347G>T p.E5783* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99476926; called by muse, mutect2, varscan2
- OR14I1 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100700511; called by muse, mutect2, varscan2
- OR14I1 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100700512; called by muse, mutect2, varscan2
- OR2AK2 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 527/1005 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1180076764, COSV100824101, COSV63559586; called by muse, mutect2, varscan2
- OR2T34 | c.682C>A p.H228N | Missense Mutation (SNP) | VAF 262/1042 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV100170228; called by muse, mutect2, varscan2
- OR4D5 | c.951A>T p.L317F | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100190086; called by muse, mutect2, varscan2
- OR5L1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 148/656 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs755707900, COSV61734051; called by muse, varscan2
- OR6Q1 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 324/620 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100110247; called by muse, mutect2, varscan2
- OVCH1 | c.2302G>A p.V768I | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV100548933; called by muse, mutect2, varscan2
- PA2G4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV57568531; called by muse, mutect2, varscan2
- PBXIP1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202026941, COSV100870107; called by muse, mutect2, varscan2
- PCDH7 | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.646); catalogued as COSV100688516; called by muse, mutect2
- PFKFB2 | c.988-1G>A p.X330_splice | Splice Site (SNP) | VAF 82/295 reads (28%) | catalogued as COSV100892032; called by muse, varscan2
- PGAM4 | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 197/236 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100431267, COSV58451268; called by muse, mutect2, varscan2
- PHC1 | c.2753C>T p.T918I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99134259; called by muse, mutect2, varscan2
- PIK3R5 | c.781G>T p.G261* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99353631; called by muse, mutect2, varscan2
- PIP4P1 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99164498; called by muse, mutect2, varscan2
- POSTN | c.1614T>A p.N538K | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101123409; called by muse, mutect2, varscan2
- POTEE | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV100388449, COSV58239217; called by muse, mutect2, varscan2
- POU6F2 | c.458T>G p.V153G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV101302783; called by muse, mutect2, varscan2
- PTPRD | c.4947G>A p.K1649= | Splice Region (SNP) | VAF 177/264 reads (67%) | catalogued as COSV100645718, COSV61941139; called by muse, mutect2, varscan2
- RELN | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 251/657 reads (38%) | catalogued as COSV100634264; called by muse, mutect2, varscan2
- REV1 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99301199; called by muse, mutect2, varscan2
- SEC24B | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 132/178 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs370271043; called by muse, mutect2, varscan2
- SEPTIN3 | c.164C>A p.T55N | Missense Mutation (SNP) | VAF 85/94 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV99352257; called by muse, mutect2, varscan2
- SESN1 | c.1330C>T p.P444S (on ENST00000356644 / NM_001199933.1; = p.P503S on NM_014454.3) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57420727; called by muse, mutect2, varscan2
- SF3A1 | c.1597A>G p.K533E | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99305582; called by muse, mutect2, varscan2
- SFTPA1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 86/116 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100957100; called by muse, mutect2, varscan2
- SLC41A1 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100900441, COSV65651003; called by muse, mutect2, varscan2
- SLC6A15 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99881215; called by muse, mutect2
- SLC6A15 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99881218; called by muse, mutect2, varscan2
- SLC6A20 | c.1383C>A p.N461K | Missense Mutation (SNP) | VAF 98/122 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100653842, COSV62071964; called by muse, mutect2, varscan2
- SPRR2D | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 47/1718 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.08); catalogued as COSV100836062; called by muse, mutect2
- SPRTN | c.1100G>C p.S367T | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99149933; called by muse, mutect2, varscan2
- STXBP5L | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 119/139 reads (86%) | catalogued as COSV99875313; called by muse, mutect2, varscan2
- SV2B | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100370798; called by muse, mutect2, varscan2
- SVEP1 | c.7361A>G p.Q2454R | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV99929401; called by muse, mutect2, varscan2
- TBC1D4 | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.998); catalogued as COSV66491162; called by muse, mutect2, varscan2
- TBX22 | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 242/275 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV100960882, COSV64785927; called by muse, mutect2, varscan2
- TENT4A | c.1640G>T p.W547L | Missense Mutation (SNP) | VAF 163/663 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100049120; called by muse, mutect2, varscan2
- TJAP1 | c.997G>A p.E333K (on ENST00000372445 / NM_001146016.1; = p.E323K on NM_080604.3) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99447031; called by muse, mutect2, varscan2
- TP53 | c.709A>T p.M237L | Missense Mutation (SNP) | VAF 250/333 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52701833, COSV52875518, COSV53198341; called by muse, varscan2
- TRAF5 | c.1001A>G p.N334S | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99807495; called by muse, mutect2, varscan2
- TRIM24 | c.1717A>G p.S573G (on ENST00000343526 / NM_015905.3; = p.S539G on NM_003852.4) | Missense Mutation (SNP) | VAF 156/419 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100631084; called by muse, mutect2, varscan2
- TRIM42 | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV99648599; called by muse, mutect2, varscan2
- TTN | c.11016C>A p.N3672K (on ENST00000591111; = p.N3626K on NM_003319.4) | Missense Mutation (SNP) | VAF 96/200 reads (48%) | catalogued as COSV100621183; called by muse, mutect2, varscan2
- UACA | c.942G>T p.Q314H | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as COSV100537605; called by muse, mutect2, varscan2
- UACA | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1488993066, COSV100537606, COSV59853617; called by muse, mutect2, varscan2
- UBE2J2 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs767229525, COSV100231261; called by muse, mutect2, varscan2
- UTP20 | c.7865T>G p.L2622W | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99882065; called by muse, mutect2, varscan2
- WDR76 | c.1049A>T p.E350V | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV99776586; called by muse, mutect2, varscan2
- ZDHHC23 | c.1094T>A p.M365K | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV100362214; called by muse, mutect2, varscan2
- ZFHX4 | c.3962C>G p.S1321* | Nonsense Mutation (SNP) | VAF 42/94 reads (45%) | catalogued as COSV99265255; called by muse, mutect2, varscan2
- ZFP82 | c.1391A>C p.K464T | Missense Mutation (SNP) | VAF 83/136 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as COSV101089210; called by muse, mutect2, varscan2
- ZIC3 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 53/55 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799198; called by muse, mutect2, varscan2
- ZNF215 | c.911G>T p.S304I | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV53493713; called by muse, mutect2, varscan2
- ZNF280B | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 240/1034 reads (23%) | catalogued as COSV100840373; called by muse, mutect2, varscan2
- ZNF343 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 36/136 reads (26%) | catalogued as COSV53854321, COSV99601536; called by muse, mutect2, varscan2
- ZNF484 | c.916A>T p.T306S | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV100214774; called by muse, varscan2
- ZNF606 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100357457, COSV62048622; called by muse, mutect2, varscan2
- ZNF831 | c.3941G>T p.W1314L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.497); catalogued as COSV100926132; called by muse, mutect2, varscan2
- ZSCAN30 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1172385557, COSV99735051; called by muse, mutect2, varscan2
- DUSP14 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ERBIN | c.1902del p.D635Mfs*50 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | called by pindel, varscan2
- ERBIN | c.1903G>T p.D635Y | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- FAM169A | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- FBXO38 | c.3140G>A p.S1047N (on ENST00000340253 / NM_205836.3; = p.S972N on NM_030793.5) | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); called by muse, varscan2
- HNRNPUL1 | c.1827dup p.D610* | Frame Shift Ins (INS) | VAF 36/91 reads (40%) | called by mutect2, pindel, varscan2
- IGKV1-27 | c.343A>T p.S115C | Missense Mutation (SNP) | VAF 136/248 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- IRAG1 | c.2555G>A p.W852* | Nonsense Mutation (SNP) | VAF 22/562 reads (4%) | called by muse, mutect2
- MAN1A2 | c.401_412del p.R134_I137del | In Frame Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, varscan2
- OR5L2 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 192/385 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); called by muse, varscan2
- OR5L2 | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 194/386 reads (50%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.654); called by muse, varscan2
- PDLIM5 | c.43_44del p.G15Ffs*7 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- STARD3NL | c.506G>T p.W169L | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STARD6 | c.228dup p.S77Ifs*6 | Frame Shift Ins (INS) | VAF 43/127 reads (34%) | called by mutect2, pindel, varscan2
- ABCA7 | c.3957G>A p.S1319= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs142705355; called by muse, mutect2, varscan2
- ANK3 | c.10674A>G p.K3558= | Silent (SNP) | VAF 85/118 reads (72%) | catalogued as COSV99779461, COSV99781104; called by muse, mutect2, varscan2
- ANKS1B | c.3219A>G p.K1073= (on ENST00000547776 / NM_152788.4; = p.K239= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV100228407; called by muse, mutect2, varscan2
- BCL2L14 | c.138G>A p.K46= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as rs1178372066, COSV99845183; called by muse, mutect2, varscan2
- CHD5 | c.2793G>C p.R931= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV99314287; called by muse, mutect2, varscan2
- CKAP5 | c.5826C>T p.L1942= (on ENST00000529230 / NM_001008938.4; = p.L1882= on NM_014756.3) | Silent (SNP) | VAF 85/328 reads (26%) | catalogued as COSV100319600; called by muse, mutect2, varscan2
- DLC1 | c.1710C>A p.S570= (on ENST00000276297 / NM_001348081.2; = p.S133= on NM_006094.5) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99364313; called by muse, mutect2, varscan2
- FAM135B | c.3678G>A p.S1226= | Silent (SNP) | VAF 205/556 reads (37%) | catalogued as rs369381577; called by muse, mutect2, varscan2
- FAM71B | c.441C>T p.G147= | Silent (SNP) | VAF 85/110 reads (77%) | catalogued as COSV100262195; called by muse, mutect2, varscan2
- FGD2 | c.600C>T p.V200= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99236407; called by muse, mutect2
- GLYR1 | c.708G>A p.T236= | Silent (SNP) | VAF 202/335 reads (60%) | catalogued as rs1191186005, COSV58928623; called by muse, mutect2, varscan2
- HDHD5 | c.483G>T p.R161= (on ENST00000336737 / NM_033070.3; = p.R131= on NM_017829.5) | Silent (SNP) | VAF 124/523 reads (24%) | catalogued as COSV99324920; called by muse, mutect2, varscan2
- IGHV4-34 | c.183C>T p.S61= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs11546809; called by mutect2, varscan2
- IL37 | c.126C>A p.T42= | Silent (SNP) | VAF 54/77 reads (70%) | catalogued as COSV99636350; called by muse, mutect2
- KRTAP27-1 | c.297G>A p.A99= | Silent (SNP) | VAF 10/215 reads (5%) | catalogued as rs1056914988, COSV67001400; called by muse, mutect2
- LPIN2 | c.1863C>G p.P621= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99858647; called by muse, mutect2, varscan2
- MARK4 | c.957G>A p.L319= | Silent (SNP) | VAF 100/1075 reads (9%) | called by muse, mutect2
- MCC | c.2418G>A p.R806= | Silent (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- MCF2L2 | c.1068G>A p.V356= | Silent (SNP) | VAF 28/630 reads (4%) | catalogued as COSV100193303; called by muse, mutect2
- MYLK3 | c.2013G>A p.V671= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV101189152; called by muse, mutect2, varscan2
- MYO7B | c.1653T>C p.I551= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as COSV101268304; called by muse, mutect2, varscan2
- NAV3 | c.4656G>T p.V1552= | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as COSV99893365; called by muse, mutect2, varscan2
- NEB | c.7488T>C p.D2496= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99425522; called by muse, mutect2, varscan2
- NIPBL | c.2281A>C p.R761= | Silent (SNP) | VAF 81/154 reads (53%) | catalogued as COSV99241596; called by muse, mutect2
- NLRP3 | c.210G>T p.V70= | Silent (SNP) | VAF 96/252 reads (38%) | catalogued as COSV100276385; called by muse, mutect2, varscan2
- OR2A12 | c.708C>T p.A236= | Silent (SNP) | VAF 237/608 reads (39%) | catalogued as rs747564117, COSV101283182; called by muse, mutect2, varscan2
- PCDH7 | c.192G>T p.V64= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100688514; called by mutect2, varscan2
- PCDHGC5 | c.1734T>G p.R578= | Silent (SNP) | VAF 178/248 reads (72%) | called by mutect2, varscan2
- POGK | c.1236A>C p.P412= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs768783825, COSV100902534, COSV63311716; called by muse, mutect2, varscan2
- PTPRZ1 | c.5037T>C p.P1679= | Silent (SNP) | VAF 82/205 reads (40%) | catalogued as COSV101100501; called by muse, mutect2, varscan2
- ROS1 | c.390C>A p.I130= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as COSV100877429; called by muse, mutect2
- RPL26L1 | c.273C>T p.N91= | Silent (SNP) | VAF 172/239 reads (72%) | catalogued as rs373992570; called by muse, mutect2, varscan2
- RYR3 | c.5997G>T p.A1999= | Silent (SNP) | VAF 187/397 reads (47%) | catalogued as COSV101213239, COSV66784909; called by muse, mutect2, varscan2
- SBNO1 | c.4110G>A p.Q1370= (on ENST00000420886; = p.Q1369= on NM_018183.5) | Silent (SNP) | VAF 99/389 reads (25%) | catalogued as COSV99929453; called by muse, mutect2, varscan2
- SCAF8 | c.1974A>G p.A658= | Silent (SNP) | VAF 231/395 reads (58%) | catalogued as rs758982206, COSV100781317; called by muse, mutect2, varscan2
- SCGN | c.159G>T p.T53= | Silent (SNP) | VAF 71/122 reads (58%) | catalogued as COSV100618809; called by muse, mutect2, varscan2
- SLC17A4 | c.681A>T p.G227= | Silent (SNP) | VAF 21/813 reads (3%) | catalogued as COSV100930637; called by muse, mutect2
- SPATA31A6 | c.2073G>T p.G691= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100253632; called by mutect2, varscan2
- TMEM202 | c.720G>T p.P240= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as COSV100499213; called by muse, mutect2, varscan2
- TPK1 | c.435G>T p.A145= | Silent (SNP) | VAF 87/213 reads (41%) | catalogued as COSV100765950; called by muse, mutect2, varscan2
- USF3 | c.2265A>T p.T755= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as COSV100325558; called by muse, mutect2, varscan2
- ZIM2 | c.1422C>A p.V474= | Silent (SNP) | VAF 68/100 reads (68%) | catalogued as COSV99689347, COSV99689665; called by muse, mutect2, varscan2
- ZNF236 | c.2572C>T p.L858= | Silent (SNP) | VAF 42/512 reads (8%) | catalogued as COSV99470780; called by muse, mutect2
- ZNF415 | c.357T>C p.T119= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV54706488; called by muse, mutect2, varscan2
- ZNF783 | c.117G>C p.T39= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV100954272; called by muse, mutect2, varscan2
- ZP4 | c.1296G>A p.Q432= | Silent (SNP) | VAF 113/260 reads (43%) | catalogued as rs1317315625, COSV100850727, COSV63911094; called by muse, mutect2, varscan2
- LRRC23 | c.*31A>G | 3'UTR (SNP) | VAF 115/220 reads (52%) | catalogued as COSV99145272; called by muse, mutect2, varscan2
